Gene-level copy-number profile of tumor specimen HTMCP-03-06-02435-01A from CGCI case HTMCP-03-06-02435, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G2; Age at diagnosis: 38.7 years (14,141 days).
Specimen HTMCP-03-06-02435-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bcdf7a5f-2726-4b83-9a56-0ddf6e5d48c4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02435-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,263 have no estimate.
https://portal.gdc.cancer.gov/files/5089fa18-8434-4172-9203-9f67bba2c06e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 24; copy number 2: 3,816; copy number 3: 19,155; copy number 4: 25,397; copy number 5: 6,196; copy number 6: 2,749; copy number 7: 939; copy number 9: 23; copy number 11: 46.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:40,970,541–41,962,130, 11 genes (within-gene range 0–2): AC099541.1, AC009743.1, MRPS31P1, CTNNB1, ULK4, AC099537.1, RN7SKP58, ATP6V0E1P2, Y_RNA, U8, RPL36P20.
- chr11:89,752,785–89,768,836, 4 genes: UBTFL2, AP003122.2, AP003122.3, AP003122.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 69 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,894,433–22,492,907, 68 genes, copy number 9–11 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 11: TRAC.

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
